Somatic mutation profile of tumor specimen C3N-03205-01 (aliquot CPT0185090006) from CPTAC case C3N-03205, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,778 days).
Specimen C3N-03205-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d6b3ba-2a35-408d-b1c7-9c72b68ec708.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03205-31 (Blood Derived Normal), aliquot CPT0185150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a66e8a-5e85-4654-84d0-1587a08a4cbb

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Del 3, Intron 1, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, RNA 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR6 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1415410192; called by muse, mutect2
- CHP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs756478431, COSV55649342; called by muse, mutect2
- CHST8 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs768133934, COSV52860765; called by muse, mutect2, varscan2
- ELP3 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs975518217; called by muse, mutect2, varscan2
- HNRNPH1 | c.788-1G>T p.X263_splice | Splice Site (SNP) | VAF 27/203 reads (13%) | catalogued as COSV61485099; called by muse, mutect2, varscan2
- ITGAD | c.2594C>A p.P865H | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66759523; called by muse, mutect2, varscan2
- LRCH1 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534736614; called by muse, mutect2, varscan2
- MOS | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV61335946; called by muse, mutect2, varscan2
- NOL4 | c.1328C>A p.S443* | Nonsense Mutation (SNP) | VAF 13/259 reads (5%) | catalogued as COSV52344254; called by muse, mutect2
- SLK | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV104410168; called by muse, mutect2, varscan2
- STK39 | c.1169A>T p.D390V | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs747339900; called by muse, mutect2, varscan2
- TCHH | c.1906A>C p.S636R | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1200070953; called by muse, varscan2
- TFE3 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1557075083; called by muse, mutect2
- ALPP | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 41/391 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIITA | c.2204A>T p.Q735L | Missense Mutation (SNP) | VAF 69/606 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CPEB4 | c.1111_1112del p.I371Ffs*21 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- ELP4 | c.712G>A p.E238K (on ENST00000350638; = p.E237K on NM_019040.5) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- MYO1B | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NAALADL2 | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2
- PDE3A | c.643_656del p.I215Rfs*68 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | called by mutect2, pindel, varscan2
- PLEKHH3 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- PRSS53 | c.243_245del p.A84del | In Frame Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- RAB38 | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RILP | c.776_781delinsGC p.K259Sfs*31 | Frame Shift Del (DEL) | VAF 34/188 reads (18%) | called by pindel, varscan2*
- SLC22A24 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TOP3B | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TUBB6 | c.1016G>C p.S339T | Missense Mutation (SNP) | VAF 66/508 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBR4 | c.3098G>T p.C1033F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2
- ZFP92 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- ZNF638 | c.5672dup p.D1892Gfs*12 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- CMTM5 | c.522G>A p.V174= (on ENST00000339180 / NM_001288746.2; = p.V107= on NM_138460.3) | Silent (SNP) | VAF 45/233 reads (19%) | catalogued as COSV100198222; called by muse, mutect2, varscan2
- DGKI | c.2604C>A p.G868= | Silent (SNP) | VAF 45/185 reads (24%) | called by muse, mutect2, varscan2
- TYR | c.909C>T p.N303= | Silent (SNP) | VAF 55/360 reads (15%) | called by muse, mutect2, varscan2
- ZBTB20 | c.1071G>A p.T357= (on ENST00000474710 / NM_001164342.2; = p.T284= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as rs777297826, COSV61846855, COSV61849443; called by muse, mutect2
- AC093582.1 | n.255C>T | RNA (SNP) | VAF 39/439 reads (9%) | called by muse, mutect2
- CSMD2 | c.8312-7508G>A | Intron (SNP) | VAF 21/300 reads (7%) | catalogued as rs377461619; called by muse, mutect2
- PCDHB8 | c.-2C>A | 5'UTR (SNP) | VAF 72/506 reads (14%) | catalogued as rs575403154; called by muse, mutect2, varscan2
